Gene-level copy-number profile of tumor specimen TCGA-AP-A0L9-01A from TCGA case TCGA-AP-A0L9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 71.7 years (26,185 days).
Specimen TCGA-AP-A0L9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.cd42ea40-356d-4b7a-a89b-36527c038425.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AP-A0L9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/426e2dc2-05b5-4819-8556-79b00b4601a9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 663; copy number 2: 15,199; copy number 3: 30,168; copy number 4: 6,910; copy number 5: 5,366; copy number 6: 1,034; copy number 7: 222; copy number 8: 142; copy number 9: 73; copy number 11: 13; copy number 14: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AP-A0L9-01A-11D-A042-01): tumor purity 0.84, ploidy 5.58, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 474 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:154,957,026–155,331,114, 40 genes, copy number 8: PYGO2, AL451085.2, SHC1, CKS1B, MIR4258, FLAD1, LENEP, ZBTB7B, DCST2, DCST1, DCST1-AS1, ADAM15, EFNA4, AL691442.1, EFNA3, Y_RNA, EFNA1, SLC50A1, DPM3, HMGN2P18, KRTCAP2, AL713999.2, TRIM46, MUC1, THBS3-AS1, MIR92B, THBS3, MTX1, AC234582.1, GBAP1, MTX1P1, GBA, FAM189B, SCAMP3, CLK2, HCN3, PKLR, FDPS, RUSC1-AS1, RUSC1.
- chr1:155,346,350–155,346,445, 1 gene, copy number 8: MIR555.
- chr3:11,060,973–13,746,638, 50 genes, copy number 7–14 (within-gene range 3–14): AC066580.1, HRH1, AC083855.2, CHCHD4P4, ATG7, AC083855.1, AC026185.1, AC022001.1, VGLL4, AC022001.2, AC022001.3, TAMM41, FANCD2P2, CYCSP12, NUP210P2, MARK2P14, AC090958.1, RN7SL147P, SYN2, ACTG1P12, TIMP4, MTCO1P5, GSTM5P1, PPARG, AC091492.1, TSEN2, RNA5SP123, RNU6-377P, MKRN2OS, MKRN2, Metazoa_SRP, RAF1, CRIP1P1, TMEM40, KRT18P17, CAND2, AC034198.2, RPL32, SNORA7A, AC034198.1, LINC02022, IQSEC1, AC069271.1, NUP210, AC027124.2, AC027124.1, HDAC11-AS1, HDAC11, FBLN2, LINC00620.
- chr3:155,375,580–155,745,071, 1 gene, copy number 9 (within-gene range 6–9): PLCH1.
- chr3:155,485,803–156,037,647, 12 genes, copy number 9: PLCH1-AS2, RPL6P7, AC104472.1, AC104472.2, C3orf33, AC104472.3, SLC33A1, AC104472.4, GMPS, AC104472.5, SETP14, VN2R1P.
- chr3:156,044,155–156,114,198, 2 genes, copy number 9: ALG1L15P, MRE11P1.
- chr3:156,175,852–156,176,911, 1 gene, copy number 9: AC091607.1.
- chr4:59,150,924–61,153,962, 13 genes, copy number 7: AC108517.2, AC108517.1, Y_RNA, AC096588.1, AC093857.1, Y_RNA, RNU6-1325P, AC092596.1, AC097655.1, LINC02496, AC105420.1, MIR548AG1, LINC02271.
- chr4:61,211,652–61,212,203, 1 gene, copy number 7: RPL17P19.
- chr5:9,363,275–10,307,902, 29 genes, copy number 7: AC091906.1, AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221, AC091905.2, AC091905.3, AC091905.1, AC091905.4, AC034229.1, AC034229.6, AC034229.5, AC034229.2, AC034229.3, AC034229.4, ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3, CMBL, Y_RNA.
- chr6:19,438,283–19,438,418, 1 gene, copy number 7: RNA5SP205.
- chr7:24,196,662–25,949,986, 29 genes, copy number 7: AC004485.1, NPY, AC003044.1, RNU6-1103P, MPP6, SUMO2P14, AC005084.1, GSDME, AC003093.1, OSBPL3, SNRPCP19, CYCS, C7orf31, AC004129.2, AC004129.1, NPVF, AC004129.3, U3, TSEN15P3, AC003985.1, AC005100.1, AC005100.2, AC091705.1, AC005165.1, AC005165.2, AC005165.3, AC018706.1, AC010719.1, MIR148A.
- chr7:90,119,299–90,238,137, 4 genes, copy number 7: AC004969.1, DPY19L2P4, STEAP1, STEAP2.
- chr7:90,251,923–90,270,216, 2 genes, copy number 7: Y_RNA, AC002064.2.
- chr7:129,756,266–130,506,465, 30 genes, copy number 8: RNA5SP244, AC084864.2, MIR182, MIR96, MIR183, AC084864.1, UBE2H, AC073320.1, Y_RNA, ZC3HC1, RNA5SP245, KLHDC10, AC087071.1, TMEM209, AC087071.2, SSMEM1, AC024085.1, CPA2, CPA4, CPA5, CPA1, CEP41, AC007938.1, MESTIT1, MEST, AC007938.5, AC007938.6, AC007938.4, AC007938.2, MIR335.
- chr7:130,507,660–130,508,282, 1 gene, copy number 8: AC007938.3.
- chr7:135,092,363–135,170,795, 1 gene, copy number 7 (within-gene range 5–7): CYREN.
- chr7:135,148,072–135,510,127, 10 genes, copy number 7: TMEM140, AC083862.1, AC083862.2, WDR91, AC009542.1, MIR6509, STRA8, SLC23A4P, CNOT4, SDHDP2.
- chr8:95,071,732–95,087,924, 1 gene, copy number 7 (within-gene range 4–7): AC068189.1.
- chr8:95,133,785–96,611,790, 21 genes, copy number 7–9: PLEKHF2, C8orf37-AS1, LINC01298, C8orf37, AC024995.1, AC083836.1, RNU6-690P, SRSF3P2, AC012339.1, GAPDHP30, AC007992.1, AP003465.2, GDF6, UQCRB, AP003465.1, MTERF3, PTDSS1, Y_RNA, AP003548.1, RNU6-1172P, SDC2.
- chr8:108,131,100–112,148,825, 40 genes, copy number 7–8: AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, AC022360.1, RNU4-37P.
- chr8:112,446,575–112,643,583, 3 genes, copy number 7: AC024996.1, RPL30P16, MIR2053.
- chr8:128,405,269–128,564,679, 1 gene, copy number 7 (within-gene range 3–7): LINC00824.
- chr9:14,475–746,106, 19 genes, copy number 7: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1.
- chr9:21,321,300–22,128,103, 34 genes, copy number 9 (within-gene range 6–9): IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr13:59,010,332–60,163,928, 8 genes, copy number 7 (within-gene range 5–7): HMGN2P39, POLR3KP1, AL159156.1, RPP40P2, RNU7-88P, DIAPH3, DIAPH3-AS1, RN7SL375P.
- chr13:109,478,739–110,307,157, 15 genes, copy number 7 (within-gene range 4–7): AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P, AL390755.2, AL390755.3, COL4A1, AL161773.1.
- chr13:110,340,958–110,341,029, 1 gene, copy number 7: MIR8073.
- chr18:21,914,369–23,956,222, 37 genes, copy number 8 (within-gene range 5–8): AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77.
- chr19:18,058,995–19,138,513, 56 genes, copy number 7 (within-gene range 4–7): IL12RB1, MAST3, AC007192.2, AC007192.1, PIK3R2, IFI30, MPV17L2, RAB3A, AC005759.1, AC008397.2, PDE4C, AC008397.1, IQCN, JUND, MIR3188, RPL39P38, LSM4, RN7SL513P, PGPEP1, GDF15, MIR3189, LRRC25, SSBP4, ISYNA1, AC010335.1, ELL, AC010335.2, AC010335.3, AC005387.1, FKBP8, AC005387.2, KXD1, AC005253.1, AC005253.2, UBA52, CRLF1, REX1BD, TMEM59L, RN7SL155P, KLHL26, CRTC1, COMP, UPF1, GDF1, CERS1, AC005197.1, COPE, AC002985.1, DDX49, HOMER3, HOMER3-AS1, RN7SL70P, SUGP2, ARMC6, SLC25A42, TMEM161A.
- chr20:53,552,770–54,070,594, 10 genes, copy number 7–9: AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756.

Autosomal genes at a single copy (total copy number 1): 658. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
